Somatic mutation profile of tumor specimen 0DGBAC from CCDI case PBBTAY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,138 days).
Specimen 0DGBAC: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05e13149-d031-4be0-8298-62b7a5520b1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGB91 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aefb1a47-761a-472d-9fdf-6038f5fda36a

The open-access MAF lists 45 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 11, Intron 4, Frame Shift Del 3, 5'UTR 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VPS13B | c.9850dup p.I3284Nfs*10 | Frame Shift Ins (INS) | VAF 94/204 reads (46%) | catalogued as rs774357106; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- APEH | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs761839473; called by muse, varscan2
- ARHGAP45 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 136/242 reads (56%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.763); catalogued as rs775003355; called by muse, mutect2, varscan2
- BX276092.9 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.279); catalogued as rs1452780421; called by muse, mutect2
- DHX16 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 151/357 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138855782; called by muse, mutect2, varscan2
- DNAH10 | c.5357G>A p.R1786H (on ENST00000409039; = p.R1725H on NM_207437.3) | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as rs368274139, COSV68995307; called by muse, mutect2, varscan2
- FBXW11 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346102267, COSV51605761; called by muse, mutect2, varscan2
- KRT18 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs746898922, COSV101184077; called by muse, mutect2, varscan2
- NME8 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs546529254, COSV52253826, COSV52254906; called by muse, mutect2, varscan2
- TET2 | c.4351C>T p.R1451W | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395976555, COSV54431982; called by muse, mutect2, varscan2
- TSPO | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs777431441, COSV61568133; called by muse, mutect2, varscan2
- AGBL1 | c.2362C>A p.L788I | Missense Mutation (SNP) | VAF 120/264 reads (45%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- BCOR | c.4647_4649del p.L1550del (on ENST00000378444 / NM_001123385.2; = p.L1516del on NM_017745.6) | In Frame Del (DEL) | VAF 76/89 reads (85%) | called by mutect2, pindel, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CFAP47 | c.3554C>A p.T1185N | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- CIRBP | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- COL1A2 | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPEB3 | c.1025A>C p.D342A | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FBXW11 | c.740_744del p.Q247Rfs*2 | Frame Shift Del (DEL) | VAF 102/249 reads (41%) | called by mutect2, pindel, varscan2
- NCAM2 | c.1944del p.D649Tfs*56 | Frame Shift Del (DEL) | VAF 118/397 reads (30%) | called by pindel, varscan2
- NOTCH1 | c.160_188del p.G54Pfs*79 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- PPCDC | c.360+8A>G | Splice Region (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- RPL22 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 77/203 reads (38%) | called by muse, mutect2, varscan2
- SIM1 | c.1882T>C p.S628P | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCHH | c.4525C>T p.R1509C | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- VPS35L | c.1928T>C p.M643T | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs1167537044; called by muse, mutect2, varscan2
- FBRSL1 | c.1062C>T p.H354= | Silent (SNP) | VAF 104/252 reads (41%) | catalogued as rs1317430576; called by muse, mutect2, varscan2
- IFI6 | c.171C>T p.P57= | Silent (SNP) | VAF 154/358 reads (43%) | catalogued as rs534851680; called by muse, mutect2, varscan2
- IGF2BP1 | c.1152G>A p.P384= | Silent (SNP) | VAF 95/237 reads (40%) | catalogued as rs1215165292; called by muse, mutect2, varscan2
- OCA2 | c.2298G>A p.P766= | Silent (SNP) | VAF 128/346 reads (37%) | catalogued as rs914937583, COSV62361383; called by muse, mutect2
- PGGHG | c.1212C>T p.A404= | Silent (SNP) | VAF 103/236 reads (44%) | catalogued as rs1158863807, COSV67140565; called by muse, mutect2, varscan2
- RETREG3 | c.483C>T p.F161= | Silent (SNP) | VAF 24/412 reads (6%) | called by muse, mutect2
- SETD1A | c.2451C>T p.N817= | Silent (SNP) | VAF 114/256 reads (45%) | catalogued as rs756814587; called by muse, mutect2, varscan2
- TJP3 | c.213C>T p.S71= | Silent (SNP) | VAF 133/474 reads (28%) | catalogued as rs369111949; called by muse, mutect2, varscan2
- UNC13A | c.2241C>T p.D747= | Silent (SNP) | VAF 94/306 reads (31%) | catalogued as rs373430076; called by muse, varscan2
- ZNF626 | c.483C>T p.N161= | Silent (SNP) | VAF 39/221 reads (18%) | catalogued as rs567636048, COSV74129659; called by muse, mutect2, varscan2
- BRD9 | c.1526-27A>G | Intron (SNP) | VAF 6/57 reads (11%) | called by muse, varscan2
- C19orf47 | c.78+72G>T | Intron (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- CACNA2D2 | chr3:50503497 G>A | 5'Flank (SNP) | VAF 44/70 reads (63%) | called by muse, varscan2
- GDPD1 | c.*1303_*1304del | 3'UTR (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- KDM1A | c.2373+42C>T | Intron (SNP) | VAF 59/168 reads (35%) | catalogued as rs751398556, COSV56503740; called by muse, mutect2, varscan2
- MT1G | c.97+66T>G | Intron (SNP) | VAF 26/296 reads (9%) | catalogued as rs545949769, COSV60090889; called by muse, mutect2
- MYCBPAP | c.-9G>C | 5'UTR (SNP) | VAF 11/97 reads (11%) | catalogued as rs747485826; called by muse, mutect2, varscan2
- MYCBPAP | c.-8G>C | 5'UTR (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
